Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6665, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6665-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. SPECIMEN DESIGNATED "Right parietal tumor consistent with glioma":
ANAPLASTIC ASTROCYTOMA, WHO GRADE iii. SEE MICROSCOPIC DESCRIPTION.
2. SPECIMEN DESIGNATED "Right parietal tumor consistent with glioma":
ANAPLASTIC ASTROCYTOMA, WHO GRADE iii. SEE MICROSCOPIC DESCRIPTION.
- [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of moderately pleomorphic neoplastic astrocytes that infiltrate cerebral grey matter and white matter. Mitotic figures are identified in tumor cells. GFAP immunohistochemical stain is positive in the tumor. Immunohistochemical stain for p53 is negative in tumor cells. Approximately 5% of tumor cell nuclei show positive staining on Ki67 immunohistochemical stain.

Congo red stain is negative in the specimen. PAS stain highlights blood vessels in the specimen. No endothelial proliferation is identified in the tumor. No necrosis is identified in the tumor specimen.

Case was reviewed in conference with [REDACTED]

Frozen Section Diagnosis:

1. Right parietal tumor consistent with glioma: Glial neoplasm, favor high grade. Frozen section diagnosis by [REDACTED]

Clinical History and Diagnosis:

Right parietal glioma

[REDACTED]

[page 2 of 3]
Source of Specimen:

- 1: Right parietal tumor consistent with glioma
- 2: Right parietal tumor consistent with glioma

Gross Description:

1. Right parietal tumor consistent with glioma: Received fresh for frozen section in a specimen container labeled with the patient's name and "#1 right parietal tumor consistent with glioma" are multiple tan-pink fragments of soft tissue measuring 1.5 x 1.0 x 0.4 cm in aggregate. Approximately one fifth of the specimen is submitted for frozen analysis. The specimen is submitted entirely as follows:

- A frozen section control
- B. Remainder of specimen

2. Right parietal tumor consistent with glioma: Received in formalin in a specimen container labeled with the patient's name and "#2 right parietal tumor consistent with glioma" are multiple fragments of tan-white soft tissue measuring 2.0 x 1.0 x 0.5 cm in aggregate. The specimen is submitted entirely in 2 cassettes.

Histology Laboratory

Part 2: Right parietal tumor consistent with glioma

CONGO RED STAIN

GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)

KI 67

P 53

PERIODIC ACID SCHIFF

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Applied Immunohistochemistry,

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

[page 3 of 3]
3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED] Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file f69ccb33-9c8d-4a90-9fb4-9dcdef7d5c42 (TCGA-CS-6665.733DD970-DDCD-40D4-903D-C8FA7B725CF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).